Somatic mutation profile of tumor specimen TCGA-A6-3810-01A (aliquot TCGA-A6-3810-01A-01D-A270-10) from TCGA case TCGA-A6-3810, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (22,999 days).
Specimen TCGA-A6-3810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fff72e5-f0b0-4ac2-9059-be82039eee1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3810-10A (Blood Derived Normal), aliquot TCGA-A6-3810-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe3e76a0-87d7-40ee-b31f-ecc7be8ebbcc

The open-access MAF lists 172 somatic variants for this specimen: 128 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 39, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, 5'UTR 1, Splice Region 1, Splice Site 1, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 90/130 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY7 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs369539863, COSV99576086; called by mutect2, varscan2
- AFAP1 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100631636; called by muse, mutect2, varscan2
- AFF2 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 136/183 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100650262; called by muse, mutect2, varscan2
- ANGPTL5 | c.485A>T p.K162I | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100527826; called by muse, mutect2, varscan2
- ANK1 | c.4139C>T p.T1380M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs755216562, COSV55873916, COSV99225499; called by muse, mutect2, varscan2
- ANKLE1 | c.1505A>T p.K502M (on ENST00000394458; = p.K448M on NM_152363.6) | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845739; called by muse, mutect2, varscan2
- APC | c.1762del p.V588Yfs*2 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as COSV57346229; called by mutect2, varscan2
- APC | c.3912del p.I1304Mfs*4 | Frame Shift Del (DEL) | VAF 48/205 reads (23%) | catalogued as COSV57363654; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4498G>A p.G1500S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99142612; called by muse, mutect2
- ARHGEF10L | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1469588059, COSV51436810; called by muse, mutect2, varscan2
- ASTL | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs144613777, COSV60904941; called by muse, mutect2, varscan2
- BSN | c.10664G>A p.R3555H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1475618613, COSV56527786; called by muse, mutect2
- BSN | c.10937G>A p.R3646Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV56516189; called by muse, mutect2, varscan2
- CACNA1A | c.4483G>A p.V1495I | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as rs1211294190, COSV100801244; called by muse, mutect2
- CACNA1F | c.5369G>A p.R1790H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs781946990, COSV59905762; called by muse, mutect2, varscan2
- CACNA1I | c.1694C>G p.S565W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100360515; called by muse, mutect2, varscan2
- CCDC172 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs748847947, COSV60938304; called by muse, mutect2, varscan2
- CDH20 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.418); catalogued as rs777777577, COSV99405595; called by muse, mutect2, varscan2
- CDHR1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 110/153 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60564616; called by muse, mutect2, varscan2
- CILP | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs60521346, COSV99973514; called by muse, mutect2, varscan2
- CNTN2 | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV100085117; called by muse, mutect2, varscan2
- CPAMD8 | c.1396G>A p.V466M (on ENST00000651564; = p.V419M on NM_015692.5) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs751013495, COSV52237252; called by muse, mutect2, varscan2
- CRACD | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs763506093, COSV51720531; called by muse, mutect2, varscan2
- CSTB | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99376949; called by muse, mutect2
- CUL3 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs772779469, COSV52367627; called by muse, mutect2, varscan2
- DMD | c.9907G>A p.A3303T | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627601; called by muse, mutect2
- DNAH5 | c.12559G>A p.A4187T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as rs141993196; called by muse, mutect2, varscan2
- DNAH8 | c.4769T>G p.V1590G | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs1361990554, COSV100545726; called by muse, mutect2, varscan2
- DST | c.19153G>A p.E6385K (on ENST00000361203 / NM_001374722.1; = p.E4082K on NM_015548.5) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376734906; called by muse, mutect2, varscan2
- ELOA2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs773426243, COSV55303678; called by muse, mutect2, varscan2
- FAM83H | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1420741574, COSV101186995; called by muse, mutect2, varscan2
- FBF1 | c.2543C>A p.A848D (on ENST00000586717; = p.A862D on NM_001319193.1) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100045229; called by muse, mutect2, varscan2
- FN1 | c.3370G>A p.G1124R | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117299; called by muse, mutect2, varscan2
- FOXH1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.386); catalogued as rs762230558, COSV100023837; called by mutect2, varscan2
- FRAS1 | c.5261A>G p.Y1754C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV53629331; called by muse, mutect2, varscan2
- GABRB3 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54674522; called by muse, mutect2, varscan2
- GABRG3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs779223196, COSV100407663; called by muse, mutect2, varscan2
- GLIS1 | c.670C>A p.R224S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV56552698; called by muse, mutect2, varscan2
- GOLIM4 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV58330869; called by muse, mutect2, varscan2
- GPC6 | c.1130C>A p.A377E | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100989109; called by muse, mutect2
- GPR182 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs753611146, COSV55626380; called by muse, mutect2, varscan2
- HAS1 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99708432; called by muse, mutect2
- HDAC6 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490916; called by muse, mutect2, varscan2
- HELZ2 | c.5026C>T p.R1676C (on ENST00000467148 / NM_001037335.2; = p.R1107C on NM_033405.3) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs141999472; called by muse, mutect2, varscan2
- HK2 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51877382; called by muse, mutect2, varscan2
- HS3ST4 | c.1338T>G p.D446E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV58809436, COSV58824064; called by muse, mutect2, varscan2
- HSF1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs148595793; called by muse, mutect2, varscan2
- INVS | c.2168A>G p.E723G | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99317627; called by muse, mutect2, varscan2
- IQSEC3 | c.1571C>T p.A524V (on ENST00000538872 / NM_001170738.2; = p.A221V on NM_015232.1) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782495678, COSV100406742; called by muse, mutect2
- IQSEC3 | c.2606G>A p.R869H (on ENST00000538872 / NM_001170738.2; = p.R566H on NM_015232.1) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV58288255; called by muse, mutect2, varscan2
- KALRN | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV53761086; called by muse, mutect2, varscan2
- KDM6B | c.3874C>G p.L1292V | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV99641639; called by muse, mutect2, varscan2
- KHDC3L | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 109/168 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762594964, COSV100951108; called by muse, mutect2, varscan2
- KIF25 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV63027424; called by muse, mutect2, varscan2
- KIRREL3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as rs779077392, COSV73107294; called by muse, mutect2, varscan2
- KPNA6 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65361266; called by muse, mutect2, varscan2
- KRTAP13-2 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV101299641; called by muse, mutect2, varscan2
- MCM6 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV51467991; called by muse, mutect2, varscan2
- MMS22L | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51517886; called by muse, mutect2, varscan2
- MPHOSPH8 | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 26/764 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV64055230, COSV64056604; called by muse, mutect2
- MYO7B | c.2775G>A p.M925I | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV101268224; called by muse, mutect2
- NALCN | c.3582G>A p.P1194= | Splice Region (SNP) | VAF 18/180 reads (10%) | catalogued as rs201831882, COSV51951314; called by muse, mutect2, varscan2
- NAV2 | c.3370G>A p.E1124K (on ENST00000396087 / NM_001244963.2; = p.E1101K on NM_145117.5) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774747436, COSV100217081; called by muse, mutect2, varscan2
- NEB | c.11662C>T p.P3888S | Missense Mutation (SNP) | VAF 113/412 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV51437997; called by muse, mutect2, varscan2
- NID2 | c.2257+2T>G p.X753_splice | Splice Site (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99356084, COSV99356653; called by muse, mutect2, varscan2
- NTRK2 | c.1693G>A p.D565N (on ENST00000323115 / NM_001369534.1; = p.D581N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV52873111; called by muse, mutect2, varscan2
- OBP2A | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs139660402; called by muse, mutect2, varscan2
- OR5K3 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV101051652; called by muse, mutect2, varscan2
- OR6C68 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); catalogued as COSV65563683; called by muse, mutect2, varscan2
- PCDH11X | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 110/310 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV53487587; called by muse, mutect2, varscan2
- PCDH15 | c.5276C>A p.P1759H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV100221875, COSV57344151; called by muse, mutect2, varscan2
- PCDHA3 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs922814873, COSV100793520; called by muse, mutect2, varscan2
- PCDHB6 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1453559918, COSV50690037; called by muse, mutect2, varscan2
- PDILT | c.779A>C p.E260A | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100199488; called by muse, mutect2, varscan2
- PFKFB1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 52/124 reads (42%) | PolyPhen benign (0.054); catalogued as rs150213595, COSV66628924; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PPFIA4 | c.3215A>G p.N1072S (on ENST00000447715; = p.N1073S on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1377096342, COSV99690620; called by muse, mutect2, varscan2
- PPP1R16B | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs1234041875, COSV55375293; called by muse, mutect2, varscan2
- PRDM9 | c.1998C>G p.C666W | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99690553; called by muse, varscan2
- PRDM9 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV57010121; called by muse, mutect2, varscan2
- PSG9 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.665); catalogued as rs771822396, COSV52485241, COSV52486656; called by muse, mutect2, varscan2
- PSMC3 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771618920, COSV54081878; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- PTX4 | c.712G>C p.A238P (on ENST00000447419 / NM_001328608.2; = p.A233P on NM_001013658.1) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.188); catalogued as COSV53518213; called by muse, mutect2, varscan2
- RASA3 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 26/225 reads (12%) | catalogued as COSV100480672; called by muse, mutect2, varscan2
- REV3L | c.5671A>G p.M1891V | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100725270; called by muse, mutect2, varscan2
- RGS18 | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 102/584 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV66509213; called by mutect2, varscan2
- RLF | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs766622773, COSV101035448; called by muse, mutect2, varscan2
- RRP1B | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs766798880, COSV61479666; called by muse, mutect2, varscan2
- SBF1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as rs578021802, COSV100817805; called by muse, mutect2, varscan2
- SCARF2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839327; called by muse, mutect2, varscan2
- SCN7A | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1420108843, COSV69273291; called by muse, mutect2, varscan2
- SDK1 | c.3539T>A p.V1180D | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV101269449; called by muse, mutect2
- SEC14L1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV66724469; called by muse, mutect2
- SEC16A | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV51534634; called by muse, mutect2, varscan2
- SFRP2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs774857018, COSV56837599; called by muse, mutect2, varscan2
- SI | c.5455G>T p.E1819* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100015804; called by muse, mutect2
- SLAMF9 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV100928144; called by muse, mutect2
- SLC25A13 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as CM099600, COSV99673723; called by muse, mutect2, varscan2
- SLC35G5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs370522572; called by muse, mutect2
- SLC38A7 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.894); catalogued as COSV99543812; called by muse, mutect2
- SLC39A5 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs199681035; called by muse, mutect2, varscan2
- SLC45A3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762101416, COSV65654711; called by muse, mutect2, varscan2
- SLC7A1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416819925, COSV101060217; called by muse, mutect2, varscan2
- SLFN13 | c.1552A>T p.S518C | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV53194581; called by muse, mutect2
- SMAD6 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324923793, COSV99994141; called by muse, varscan2
- SMPD4 | c.2200C>T p.P734S (on ENST00000409031 / NM_017951.4; = p.P705S on NM_017751.4) | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60079516; called by muse, mutect2, varscan2
- SPART | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 253/387 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as rs1036407360, COSV100768526; called by muse, mutect2, varscan2
- SPON2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376213322; called by muse, mutect2, varscan2
- SUN2 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99325592; called by mutect2, varscan2
- SVIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780103291, COSV62602943; called by muse, mutect2, varscan2
- TLL1 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99285641, COSV99286566, COSV99287563; called by muse, mutect2
- TNXB | c.7752C>A p.Y2584* (on ENST00000647633; = p.Y2337* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/229 reads (20%) | catalogued as COSV100926394; called by muse, mutect2, varscan2
- TRIM71 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101070453; called by muse, mutect2, varscan2
- TUBGCP6 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV99955699; called by muse, mutect2, varscan2
- UNC13C | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs755928094, COSV52901372; called by muse, mutect2, varscan2
- WHAMM | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54497887; called by muse, mutect2, varscan2
- WWP1 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV55361872; called by muse, mutect2, varscan2
- ZBTB46 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs375790108; called by muse, mutect2, varscan2
- ZEB2 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100356177; called by muse, mutect2, varscan2
- ZNF184 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV53004996; called by muse, mutect2, varscan2
- ZNF354C | c.225A>T p.R75S | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59609189; called by muse, varscan2
- ZNF407 | c.4018A>G p.I1340V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753731025, COSV55263846; called by muse, mutect2
- ZNF559 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV57835075, COSV57836511; called by muse, mutect2, varscan2
- ZNF570 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57580136; called by muse, mutect2, varscan2
- ZNF649 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV61616909, COSV61617282; called by muse, mutect2, varscan2
- ZNF808 | c.2018A>T p.H673L | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100707991; called by muse, mutect2, varscan2
- ADGRG5 | c.789G>A p.S263= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs368136947; called by muse, varscan2
- ANXA2R | c.546G>A p.A182= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as rs759777326, COSV59215072; called by muse, mutect2, varscan2
- C2orf16 | c.1584G>A p.T528= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV62675972; called by muse, mutect2
- CAPG | c.747A>G p.A249= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV99809455; called by muse, mutect2, varscan2
- CCDC137 | c.819C>T p.H273= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs377260728; called by muse, mutect2, varscan2
- CHRNE | c.834C>T p.N278= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as rs996197218, COSV99545011; called by muse, mutect2, varscan2
- COL18A1 | c.2265G>A p.G755= (on ENST00000359759 / NM_130444.3; = p.G520= on NM_030582.4) | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV100700735; called by muse, mutect2, varscan2
- CYP2C9 | c.240T>C p.Y80= | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as rs200794294, COSV53250876; called by muse, mutect2, varscan2
- DNMT3B | c.2361A>G p.Q787= | Silent (SNP) | VAF 19/252 reads (8%) | catalogued as rs369258965; called by muse, mutect2
- FASTKD1 | c.273T>C p.Y91= | Silent (SNP) | VAF 72/345 reads (21%) | catalogued as rs1275248373, COSV70007086; called by muse, mutect2, varscan2
- FBXO6 | c.189C>T p.F63= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs780663319, COSV100951024; called by muse, mutect2, varscan2
- FUT1 | c.639C>T p.T213= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV59569330; called by muse, mutect2
- ITGBL1 | c.150C>T p.R50= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV101098023; called by muse, mutect2
- JPH2 | c.492G>A p.S164= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1412580937, COSV65904644; called by muse, mutect2, varscan2
- MLXIP | c.459G>A p.K153= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs1312045153, COSV59836868; called by muse, mutect2, varscan2
- MYCBP2 | c.10638C>T p.V3546= (on ENST00000357337; = p.V3584= on NM_015057.5) | Silent (SNP) | VAF 46/830 reads (6%) | catalogued as COSV62029971; called by muse, mutect2
- MYO1D | c.2496A>G p.P832= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV59018962; called by muse, mutect2, varscan2
- NAALADL1 | c.348C>T p.V116= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs768018089, COSV100368108; called by muse, mutect2, varscan2
- NEK1 | c.36A>G p.E12= | Silent (SNP) | VAF 115/326 reads (35%) | catalogued as COSV71457283; called by muse, mutect2, varscan2
- NFYA | c.129C>T p.S43= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs138225735; called by muse, mutect2, varscan2
- NOTCH4 | c.5866C>T p.L1956= | Silent (SNP) | VAF 47/225 reads (21%) | catalogued as COSV100900716; called by muse, mutect2, varscan2
- OR10H2 | c.375C>A p.A125= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV100008790; called by muse, mutect2, varscan2
- OR2M5 | c.550C>T p.L184= | Silent (SNP) | VAF 62/287 reads (22%) | catalogued as COSV63546084, COSV63546697; called by muse, mutect2, varscan2
- OR4X1 | c.648C>T p.Y216= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV60723397; called by muse, mutect2, varscan2
- PARD3B | c.2124G>A p.S708= | Silent (SNP) | VAF 28/470 reads (6%) | catalogued as rs200496137, COSV100593752; called by muse, mutect2
- PCDHB1 | c.183G>A p.A61= | Silent (SNP) | VAF 87/178 reads (49%) | catalogued as COSV60632074; called by muse, mutect2, varscan2
- PCDHB8 | c.2133G>A p.A711= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as rs1554281623, COSV50753657; called by muse, mutect2, varscan2
- PRSS55 | c.504C>T p.L168= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs560455180, COSV60808840, COSV60809562; called by muse, mutect2, varscan2
- PYGL | c.1587T>C p.D529= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1171142071, COSV53587313; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SCAF4 | c.687T>C p.A229= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV54589947; called by muse, mutect2, varscan2
- SLC22A4 | c.1176G>A p.L392= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs779825520, COSV52359242; called by muse, mutect2
- SLC34A3 | c.330G>A p.K110= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs753206614, COSV100746674; called by muse, mutect2, varscan2
- SPATA17 | c.6C>T p.A2= | Silent (SNP) | VAF 17/243 reads (7%) | catalogued as COSV100861173; called by muse, mutect2
- STEAP3 | c.1374C>A p.L458= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV100713334, COSV61529045; called by muse, mutect2
- TKTL2 | c.12C>T p.N4= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as rs759652519, COSV54919941; called by muse, mutect2
- TRIL | c.177C>T p.H59= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as COSV59867564; called by muse, mutect2, varscan2
- ZBED9 | c.1467T>A p.T489= | Silent (SNP) | VAF 47/315 reads (15%) | catalogued as COSV101509270; called by muse, mutect2, varscan2
- ZNF385B | c.1455G>A p.P485= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs758213417, COSV100416067; called by muse, mutect2, varscan2
- LHFPL3 | c.-1G>C | 5'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as COSV101308411; called by muse, mutect2, varscan2
- MIR412 | n.79G>A | RNA (SNP) | VAF 50/119 reads (42%) | catalogued as rs368964407; called by muse, mutect2, varscan2
- NDUFA10 | c.999+7892C>G | Intron (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99401483; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3350C>T | Intron (SNP) | VAF 15/30 reads (50%) | catalogued as rs139794100, COSV60361114; called by muse, varscan2
- ZNF578 | chr19:52451489 C>T | 5'Flank (SNP) | VAF 8/24 reads (33%) | catalogued as rs959580253, COSV56519421; called by muse, mutect2
